Gene-level copy-number profile of tumor specimen ALCH-B2UD-TTP1-A from ALCHEMIST case ALCH-B2UD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.0 years (19,343 days).
Specimen ALCH-B2UD-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2884b0c3-e8a6-4a95-b216-94f12a72cd04.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2UD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/1a3f3ae0-f06b-4e2b-bb43-56cfa4bf8bad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 12,553; copy number 2: 40,666; copy number 3: 4,651; copy number 4: 22; copy number 5: 916; copy number 7: 2; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,652,263–31,704,319, 1 gene (within-gene range 0–1): COL16A1.
- chr2:44,921,077–44,946,071, 11 genes (within-gene range 0–2): LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3.
- chr3:49,674,014–49,723,973, 6 genes: APEH, MST1, AC099668.1, RNF123, AMIGO3, GMPPB.
- chr7:76,959,835–77,043,775, 1 gene (within-gene range 0–2): DTX2P1-UPK3BP1-PMS2P11.
- chr7:76,978,617–77,043,776, 7 genes (within-gene range 0–2): DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,828,092–41,848,155, 3 genes (within-gene range 0–1): JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–1): RNA5SP393.
- chr16:81,463,892–81,533,966, 4 genes (within-gene range 0–1): AC092139.1, PPIAP51, AC092139.2, MIR7854.
- chr17:12,973,033–13,018,065, 4 genes (within-gene range 0–2): AC005274.1, AC005277.2, AC005277.1, ELAC2.
- chr22:23,834,503–23,839,128, 1 gene (within-gene range 0–1): DERL3.
- chr22:43,132,209–43,187,134, 3 genes: MCAT, TSPO, TTLL12.
- chr22:43,212,674–43,239,010, 2 genes (within-gene range 0–1): SCUBE1-AS2, Z82214.1.
- chr22:45,875,932–45,977,162, 3 genes (within-gene range 0–1): BX324167.2, BX324167.1, WNT7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 919 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–163,076,802, 857 genes, copy number 5 (broad region; genes not listed).
- chr1:179,082,070–179,271,266, 10 genes, copy number 5: TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4.
- chr11:69,414,307–70,075,469, 18 genes, copy number 5: AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P.
- chr11:86,791,059–86,952,910, 1 gene, copy number 5 (within-gene range 2–5): PRSS23.
- chr11:86,892,214–87,328,824, 9 genes, copy number 5 (within-gene range 3–5): AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1, AP001102.1.
- chr11:92,336,032–93,221,630, 19 genes, copy number 5: NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1.
- chr14:18,333,726–18,341,859, 1 gene, copy number 11: CR383658.1.
- chr17:46,511,511–46,579,691, 4 genes, copy number 5–7: LRRC37A2, ARL17A, RN7SL199P, FAM215B.

Autosomal genes at a single copy (total copy number 1): 10,230. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
